Somatic mutation profile of tumor specimen TARGET-10-PATHGY-09A (aliquot TARGET-10-PATHGY-09A-01D) from TARGET case TARGET-10-PATHGY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,319 days).
Specimen TARGET-10-PATHGY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4595ad7a-cd43-4171-b7c5-0371608af913.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATHGY-14A (Bone Marrow Normal), aliquot TARGET-10-PATHGY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb6c790d-b7ca-4e7b-a1db-8b5abe1115d4

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Intron 4, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as rs1463828394, CM1514965, COSV57138314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ARHGAP44 | c.1776C>A p.S592R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV52399010; called by muse, mutect2, varscan2
- ASH1L | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV64212047; called by muse, mutect2, varscan2
- ASPN | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65016518; called by muse, mutect2, varscan2
- CD177 | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV65122206; called by muse, varscan2
- CSMD3 | c.2179G>A p.A727T (on ENST00000297405 / NM_001363185.1; = p.A623T on NM_052900.3) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as rs747380854, COSV52276014; called by muse, mutect2, varscan2
- DACT3 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV67251154; called by muse, mutect2, varscan2
- EXD3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs759697078, COSV59808238; called by muse, mutect2, varscan2
- FCRL5 | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV62518510; called by muse, mutect2, varscan2
- FREM2 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs533045176, COSV54827471; called by muse, mutect2, varscan2
- GRM7 | c.1586C>A p.P529Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV63161097; called by muse, mutect2
- IKZF1 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58790212; called by muse, mutect2, varscan2
- LMO4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV65170246; called by muse, mutect2, varscan2
- MUSK | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378295933; called by muse, mutect2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- NYNRIN | c.4916C>A p.A1639D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV66844222; called by muse, mutect2, varscan2
- OLFML2A | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs781545777, COSV56582497; called by muse, mutect2, varscan2
- OR14J1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147619517; called by muse, mutect2, varscan2
- PLK2 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV57109265; called by muse, mutect2, varscan2
- PPFIA2 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV61047637; called by muse, mutect2, varscan2
- PSD4 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV55529128; called by muse, mutect2, varscan2
- PZP | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs763965983, COSV54367584; called by muse, mutect2, varscan2
- RILP | c.700C>A p.R234S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53957536; called by muse, mutect2
- RIMS2 | c.3146G>A p.R1049H (on ENST00000666250 / NM_001348490.2; = p.R857H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs995050197, COSV51669002; called by muse, mutect2, varscan2
- TRAPPC8 | c.3240T>G p.N1080K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV51975730; called by muse, mutect2, varscan2
- TUB | c.652C>T p.R218C (on ENST00000299506 / NM_177972.3; = p.R273C on NM_003320.4) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771327456, COSV55109448; called by muse, mutect2, varscan2
- ZFHX4 | c.5804G>C p.G1935A | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV50683820, COSV51485575; called by muse, mutect2, varscan2
- ALKBH4 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CWC25 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF6 | c.138+4_138+5insCCCTCGATCGTAA | Frame Shift Ins (INS) | VAF 19/23 reads (83%) | called by mutect2, pindel, varscan2
- GNA11 | c.255C>T p.T85= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs140204057, COSV50017662, COSV99312823; called by muse, mutect2, varscan2
- ICAM5 | c.2139G>A p.Q713= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as rs762187540; called by muse, mutect2, varscan2
- MAPK15 | c.24C>T p.R8= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- PEG3 | c.2385G>T p.G795= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV55649437; called by muse, mutect2, varscan2
- PLAA | c.978T>C p.T326= | Silent (SNP) | VAF 49/149 reads (33%) | catalogued as rs1183288248; called by muse, mutect2, varscan2
- PLS3 | c.1278C>T p.A426= | Silent (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1104C>T p.V368= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- TENM4 | c.8262C>T p.S2754= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as rs370068866; called by muse, mutect2, varscan2
- USP34 | c.6237A>G p.K2079= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV68401809; called by muse, mutect2, varscan2
- ADRA1A | chr8:26765958 C>T | 3'Flank (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99371866; called by muse, mutect2, varscan2
- CCDC40 | c.677-51T>C | Intron (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- CREB3 | c.129+44A>C | Intron (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- MS4A7 | c.283-50C>A | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- VTI1A | c.428-33969C>A | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
